MMRF case MMRF_2113 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/833d9bc8-be66-43ff-aafa-4b9d90afff5f

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 71 years; Vital status: Dead; Days to death: 465 days (1.3 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 71.9 years (26,277 days); ISS stage: III; Days to last known disease status: 465 days (1.3 years); Days to last follow up: 465 days (1.3 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 116 days.
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 123 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 465.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -24 (ECOG 2): M Protein 5.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 223 mg/dL; Immunoglobulin G 4.81 g/L; Immunoglobulin A 0.71 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 6.73 µg/mL; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 5.21 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.89 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 151 µmol/L; Blood Urea Nitrogen 12.9 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 5.7 g/dL; Glucose 5.61 mmol/L.
- Day 60 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 247 mg/dL; Immunoglobulin G 4.51 g/L; Immunoglobulin A 1.06 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 4.05 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 194 µmol/L; Blood Urea Nitrogen 19.6 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 5.9 g/dL; Glucose 4.84 mmol/L.
- Day 151 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 18.6 mg/dL; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 3.95 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 225 µmol/L; Blood Urea Nitrogen 14.3 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Glucose 6.55 mmol/L.

Other clinical attributes
- Day -24: Weight: 121 kg; Height: 177 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2113_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -24 days.
- Sample MMRF_2113_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -24 days.
